Somatic mutation profile of tumor specimen C3N-00511-03 (aliquot CPT0078250006_1) from CPTAC case C3N-00511, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 45.1 years (16,455 days).
Specimen C3N-00511-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e5ce37-1303-4388-bc90-1bc1a568cf8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00511-31 (Blood Derived Normal), aliquot CPT0078310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c87765e4-ea35-4dca-a07b-b880e0753c89

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Intron 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 120/507 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 165/655 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD35 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1553739222, COSV100841784, COSV62911158; called by muse, mutect2, varscan2
- ASPM | c.8379G>A p.M2793I | Missense Mutation (SNP) | VAF 192/1178 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376057172; called by muse, mutect2, varscan2
- ATP6V1A | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759887224, COSV56363383; called by muse, mutect2, varscan2
- C4orf54 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs753181667; called by muse, mutect2, varscan2
- CADPS | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV51901891; called by muse, mutect2, varscan2
- CHST15 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 84/488 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1338359559; called by muse, mutect2, varscan2
- CPXM2 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 53/465 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs762600262, COSV53860503; called by muse, mutect2, varscan2
- DENND2A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs766779073, COSV52050018; called by muse, mutect2, varscan2
- DOCK2 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 106/531 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.711); catalogued as rs145262338, COSV99915170; called by muse, mutect2, varscan2
- DSCAM | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747625181, COSV68634704; called by muse, mutect2, varscan2
- EGR1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 101/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122422; called by muse, mutect2, varscan2
- GALNT6 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 115/603 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62542092; called by muse, mutect2, varscan2
- GPR26 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 134/693 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as rs775340633; called by muse, mutect2, varscan2
- MAGEB17 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1446914265, COSV61556834; called by muse, mutect2, varscan2
- NCKAP1L | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 107/562 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs370847426; called by muse, mutect2, varscan2
- NID1 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 160/831 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs536352898, COSV51615314; called by muse, mutect2, varscan2
- PCDHGA6 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 189/1043 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as rs1211342702, COSV53899875; called by muse, mutect2, varscan2
- POLA1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 13/420 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV66887556; called by muse, mutect2
- POU2F1 | c.992C>G p.A331G (on ENST00000541643 / NM_001365848.1; = p.A354G on NM_002697.4) | Missense Mutation (SNP) | VAF 61/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54823646; called by muse, mutect2, varscan2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 67/259 reads (26%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- SAR1A | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV64698139; called by muse, mutect2, varscan2
- TEAD2 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 119/635 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV60874074; called by muse, mutect2, varscan2
- TMEM132A | c.2629C>T p.R877C (on ENST00000453848 / NM_178031.3; = p.R878C on NM_017870.4) | Missense Mutation (SNP) | VAF 88/565 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1314490080, COSV50019253; called by muse, mutect2, varscan2
- VPS13B | c.2653G>C p.D885H | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV62160790; called by muse, mutect2
- CLDND2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 116/670 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CROT | c.1482G>C p.M494I | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EFL1 | c.932+1G>C p.X311_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- FILIP1L | c.1837A>T p.K613* (on ENST00000354552 / NM_182909.3; = p.K373* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- HTR3B | c.258+1G>C p.X86_splice | Splice Site (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- LGALS9 | c.640C>T p.P214S (on ENST00000395473 / NM_009587.3; = p.P182S on NM_002308.4) | Missense Mutation (SNP) | VAF 134/554 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- MYH10 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 15/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NABP1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 89/435 reads (20%) | called by muse, mutect2, varscan2
- PDE1C | c.363C>G p.S121R | Missense Mutation (SNP) | VAF 90/435 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLC44A2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 178/945 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ST14 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 310/1043 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- TRIM28 | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTPA | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 107/510 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP40 | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- XRN1 | c.5048del p.T1683Nfs*29 | Frame Shift Del (DEL) | VAF 59/315 reads (19%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1385A>T p.N462I | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.276); called by muse, varscan2
- ZNF792 | c.1750C>G p.H584D | Missense Mutation (SNP) | VAF 83/455 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- BICRA | c.1731G>A p.P577= | Silent (SNP) | VAF 36/178 reads (20%) | catalogued as rs1450389334; called by muse, mutect2, varscan2
- CDON | c.1725T>A p.S575= | Silent (SNP) | VAF 176/879 reads (20%) | called by muse, mutect2, varscan2
- CRYBG2 | c.3555G>T p.V1185= | Silent (SNP) | VAF 62/480 reads (13%) | called by muse, mutect2, varscan2
- ENOX1 | c.789G>A p.E263= | Silent (SNP) | VAF 63/309 reads (20%) | catalogued as COSV54921473; called by muse, mutect2, varscan2
- HCCS | c.654C>T p.C218= | Silent (SNP) | VAF 126/635 reads (20%) | catalogued as rs775880525, COSV58239116; called by muse, mutect2, varscan2
- KRT72 | c.1140C>T p.C380= | Silent (SNP) | VAF 115/557 reads (21%) | catalogued as rs199978375, COSV53373473; called by muse, mutect2, varscan2
- LAS1L | c.1260C>T p.L420= | Silent (SNP) | VAF 141/788 reads (18%) | called by muse, mutect2, varscan2
- MTPAP | c.1515T>C p.S505= | Silent (SNP) | VAF 146/2064 reads (7%) | called by muse, mutect2
- PID1 | c.540C>T p.F180= (on ENST00000354069 / NM_001330156.1; = p.F178= on NM_017933.5) | Silent (SNP) | VAF 191/971 reads (20%) | catalogued as rs749402709, COSV62472386; called by muse, mutect2, varscan2
- PVRIG | c.774G>A p.A258= | Silent (SNP) | VAF 50/213 reads (23%) | catalogued as rs556053924, COSV52782082; called by muse, mutect2, varscan2
- SFTPC | c.141C>T p.V47= | Silent (SNP) | VAF 264/1373 reads (19%) | catalogued as rs764818190; called by muse, mutect2, varscan2
- SNTA1 | c.777G>A p.S259= | Silent (SNP) | VAF 292/1438 reads (20%) | catalogued as rs1202456575; called by muse, mutect2, varscan2
- SZT2 | c.7596T>C p.F2532= (on ENST00000634258 / NM_001365999.1; = p.F2475= on NM_015284.4) | Silent (SNP) | VAF 48/300 reads (16%) | called by muse, mutect2, varscan2
- ZNF71 | c.1194C>T p.I398= | Silent (SNP) | VAF 122/754 reads (16%) | catalogued as rs1051755100, COSV60148032; called by muse, mutect2, varscan2
- DERL1 | c.154-21T>C | Intron (SNP) | VAF 67/332 reads (20%) | called by muse, mutect2, varscan2
- LAMA1 | c.1563+10G>A | Intron (SNP) | VAF 166/872 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11407A>G | Intron (SNP) | VAF 147/764 reads (19%) | called by muse, mutect2, varscan2
- PRAME | chr22:22562955 G>A | 5'Flank (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2
